Surgical pathology report (de-identified scan), TCGA case TCGA-HG-A2PA, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-HG-A2PA-01A (Primary Tumor).

[page 1 of 3]
TSS

SPECIMENS:

- A. LEFT PELVIC LYMPH NODE
- B. LEFT PELVIC LYMPH NODES
- C. RIGHT PELVIC LYMPH NODES
- D. UTERUS AND CERVIX
- E. PARA-AORTIC LYMPH NODES
- F. APPENDIX

ICA-0-3
carcinoma, squamous cell, nos 8070/3
Site: cervix, nos 853.9
fw 8/24/11

SPECIMEN(S):

- A. LEFT PELVIC LYMPH NODE
- B. LEFT PELVIC LYMPH NODES
- C. RIGHT PELVIC LYMPH NODES
- D. UTERUS AND CERVIX
- E. PARA-AORTIC LYMPH NODES
- F. APPENDIX

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA-left pelvic lymph node: Negative for squamous cell carcinoma; diagnosis called by Dr. to Dr. at

D: Uterus, TAH (GROSS). 3.5 cm fungating tumor involving exo/endo cervix and likely lower uterine segment. Closest mucosal margin 1.5 posterior. Called by Dr. to Dr. at

DIAGNOSIS:

- A. LYMPH NODE, LEFT PELVIC, EXCISION:
- REACTIVE LYMPH NODE (0/1)
- B. LYMPH NODES, LEFT PELVIC, EXCISION:
- REACTIVE LYMPH NODES (0/13)
- C. LYMPH NODES, RIGHT PELVIC, EXCISION:
- REACTIVE LYMPH NODES (0/8)
- D. UTERUS AND CERVIX, RADICAL HYSTERECTOMY:
- MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA OF THE CERVIX MEASURING 8 X 6 CM, IT IS OF 1.5 CM OF DEPTH OF STROMAL INVASION AND IT IS INVOLVING THE ENDOMETRIUM.
- PARAMETRIUM AND VAGINAL MARGIN ARE FREE OF TUMOR.
- LYMPHATIC INVASION IS SEEN.
- SECRETORY ENDOMETRIUM WITH CHRONIC ENDOMETRITIS.
- INTRA-UTERINE DEVICE (GROSS)
- SEE SYNOPTIC REPORT.
- E. LYMPH NODES, PARA-AORTIC, EXCISION:
- REACTIVE LYMPH NODES (0/4).
- F. APPENDIX, APPENDECTOMY:
- APPENDIX WITH NO PATHOLOGIC ABNORMALITIES.

SYNOPTIC REPORT - UTERINE CERVIX

Specimen Type: Radical hysterectomy
Tumor Site: Anterior and Posterior cervix
Tumor Size: Greatest dimension: 8cm
Additional dimensions: 6cm x 2.5cm
Other Organs Present: Vagina, Uterine corpus and Appendix

WHO CLASSIFICATION

Squamous cell carcinoma, NOS 8070/3
Histologic Grade: G2: Moderately differentiated
Depth of Invasion: Invasion present
Depth: 1.5cm
Horizontal spread: 8cm

[page 2 of 3]
TSS: .

Extent of Invasion: Uterine involvement
No Parametrial involvement
No Vaginal involvement
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L): Present
Margins: Margins uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 1cm
Specific margin: vaginal mucosa
Distance of invasive carcinoma from parametrium: 1.5cm
Lymph Node Dissection: Right pelvic 0 / 8 Left pelvic 0 / 14 Para-aortic 0 / 8
Non-Lymph Node Metastases: None
Other Pathologic Findings: chronic endometriosis
Pathologic Staging (pTNM [FIGO]): pT 1b2 N 0 M X

GROSS DESCRIPTION:

A. LEFT PELVIC LYMPH NODE

Received fresh labeled with matching patient identifiers is a 2.7 x 1.8 x 1.2 cm lymph node. Specimen is serially sectioned and has a uniform pink-tan cut surface. Touch prep is performed and the specimen is submitted entirely for frozen section diagnosis in cassettes FSA1-FSA3.

B. LEFT PELVIC LYMPH NODES

Received in formalin labeled with the patient's identification and "left pelvic lymph nodes" are 8 x 5 x 2cm of adipose tissue, within which, thirteen possible lymph nodes are identified. The nodes range from 0.2 cm to 4.0 x 1.5 x 0.7 cm. The cut surfaces are firm white to tan-pink. The nodes are entirely submitted:

- B1-five lymph nodes
- B2-four lymph nodes
- B3-one bisected lymph node
- B4-B5-one lymph node, serially sectioned
- B6-B7-one lymph node, serially sectioned
- B8-B11-one lymph node, serially sectioned

C. RIGHT PELVIC LYMPH NODES

Received in formalin labeled with the patient's identification and "right pelvic lymph nodes" are 7.5 x 5.5 x 2.0 cm of adipose tissue, within which, ten possible lymph nodes are identified. The nodes range from 0.5 cm to 4.5 x 1.0 x 0.6 cm. The cut surfaces are firm white to tan-pink. Representative sections:

- C1- two bisected lymph nodes (one node inked blue)
- C2-one bisected lymph node
- C3-one bisected lymph node
- C4-two lymph nodes
- C5-one lymph node
- C6-8 one lymph node, serially sectioned.

D. UTERUS AND CERVIX:

Specimen is labeled "uterus and cervix" and consists of a 265 gram radical hysterectomy specimen. The uterus measures 6.5 x 7 x 5 cm. The cervix measuring 5 x 7 x 6 cm. The right parametrium soft tissue measures 2.0 x 1.0 x 0.5 cm. The left parametrium soft tissue measures 2 x 1 x 0.6 cm. Both are unremarkable. The serosa of the posterior uterus is entirely inked black, and the anterior is entirely inked blue. The uterus is laterally bisected along the longitudinal axis to reveal fungating 8 x 6 x 2.5 cm mass originating from the cervix and involving a vast majority of the endometrial cavity. The mass is white, soft, and friable. It is at least 2cm of depth of invasion at the anterior cervix and 1.5cm at the posterior cervix. It is at 1.0 cm from the vaginal mucosal margin and at 1.5 cm from the nearest parametrium (right). Also, the uterine cavity showed a T shape intra-uterine device (3.5 x 3 cm). The endometrial cavity is 3.3 cm from cornu to cornu, and 5 cm from superior to inferior. The myometrium has maximum thickness of 3.5cm. The endometrium is of 0.3 cm thick. The following representative sections are submitted:

- D1: right parametrium
- D2: left parametrium
- D3: right cul de sac tissue.
- D4: left cul de sac tissue.
- D5-D9: complete cross section through the anterior cervix (D7 and D8 are one section from

[page 3 of 3]
TSS:

superior to inferior, respectively) (D5 also contains the nearest vaginal margin)

D10: additional vaginal margin

D11-D13: sections through the posterior cervix

D14: complete cross section of the myometrium from the anterior cavity

D15: complete cross section from the posterior myometrium and cavity

D16-D17: uninvolved posterior and anterior upper endometrium.

E. PARA-AORTIC LYMPH NODES

Received in formalin labeled with the patient's identification and "para-aortic lymph nodes" are four lymph nodes, ranging from 0.5 x 0.5 x 0.3 cm to 1.5 x 0.8 x 0.5 cm. The cut surfaces are firm tan-pink. Entirely submitted:

E1- two bisected lymph nodes (one inked black, one inked blue)

E2-one whole lymph node (inked blue) and one bisected (inked black)

F. APPENDIX

Received in formalin labeled with the patient's identification and "appendix" is a 6.5 x 0.5 x 0.5 cm vermiform appendix. It has a smooth tan-pink serosa. It has an intact 0.3 cm wall. The lumen is dilated, proximally, ranging from 0.1 cm to 0.6 cm, and contains soft feces. No tumor is identified. Representative sections, E1.

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Cervical cancer

Microscopic/Diagnostic Dictation:, ,

Microscopic/Diagnostic Dictation:, M.D., PATHOLOGIST, .

Microscopic/Diagnostic Dictation:, M.D., PATHOLOGIST,

Final Review: M.D., PATHOLOGIST, .

Final Review:, M.D., PATHOLOGIST.

Final Review, M.D., PATHOLOGIST, ,

Final Review, M.D., PATHOLOGIST,

Final, M.D., PATHOLOGIST,

Source: NCI Genomic Data Commons file 35727128-a2b1-4ccb-88df-588e1618c4ac (TCGA-HG-A2PA.63D65B11-EE47-4B19-A811-56D61DB0D7EC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).